Somatic mutation profile of tumor specimen 0DU9N4 from CCDI case PBCLAE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,900 days).
Specimen 0DU9N4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7aeafcf-192c-4ad8-ad0a-1bf205987226.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9NJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/797e8f46-1ad7-4ee3-905a-f3a6a9c5e574

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC187 | c.311C>T p.P104L (on ENST00000638797 / NM_001378188.1; = p.P6L on NM_001291516.1) | Missense Mutation (SNP) | VAF 106/578 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.564); catalogued as rs967086427; called by muse, mutect2, varscan2
- ENAM | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 128/806 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as COSV68535287; called by muse, mutect2, varscan2
- CHST15 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 24/692 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.251); called by muse, mutect2
- TOMM34 | c.722A>G p.K241R | Missense Mutation (SNP) | VAF 31/750 reads (4%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.972); called by muse, mutect2
- SGCZ | c.-46G>C | 5'UTR (SNP) | VAF 45/166 reads (27%) | called by muse, mutect2, varscan2
